Gene-level copy-number profile of tumor specimen TCGA-78-8662-01A from TCGA case TCGA-78-8662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 53.6 years (19,563 days).
Specimen TCGA-78-8662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.482cf036-d94b-43da-9aee-4952684b4f75.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-8662-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2dae210d-33c7-4df2-9fb9-22a1d5f29fbd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 3,992; copy number 2: 26,875; copy number 3: 16,315; copy number 4: 8,894; copy number 5: 2,445; copy number 6: 362; copy number 7: 341; copy number 8: 374; copy number 9: 133; copy number 10: 50; copy number 12: 4; copy number 13: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-8662-01A-11D-2389-01): tumor purity 0.79, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–3): PTPRD.
- chr9:9,442,060–11,436,244, 11 genes (within-gene range 0–3): RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,722 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,813,225–161,964,070, 630 genes, copy number 5–7 (broad region; genes not listed).
- chr1:214,344,172–216,423,448, 18 genes, copy number 5 (within-gene range 3–5): AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2.
- chr1:230,592,660–230,802,003, 7 genes, copy number 5: LINC01737, AL158214.1, COG2, AL158214.2, AGT, AL512328.1, CAPN9.
- chr2:49,563,388–52,961,452, 28 genes, copy number 5: AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr2:78,088,729–84,040,720, 50 genes, copy number 5: AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1.
- chr2:103,275,904–110,245,420, 139 genes, copy number 5–6 (broad region; genes not listed).
- chr2:162,318,840–167,631,541, 42 genes, copy number 5–6 (within-gene range 3–6): GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1, CSRNP3, GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P.
- chr2:178,828,349–180,007,297, 13 genes, copy number 9–12: AC092640.1, CCDC141, RNU7-104P, RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22.
- chr3:93,843,764–96,814,407, 27 genes, copy number 6: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr3:165,206,929–175,810,548, 133 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:175,609,479–177,767,379, 28 genes, copy number 6: RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4.
- chr3:195,746,765–198,222,513, 98 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–8,014,804, 159 genes, copy number 5 (broad region; genes not listed).
- chr5:17,684,584–31,329,146, 120 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:10,213,881–10,222,161, 2 genes, copy number 6: AL354868.1, RNU6ATAC21P.
- chr6:41,026,895–65,707,226, 390 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr7:4,511,959–49,587,165, 783 genes, copy number 5 (broad region; genes not listed).
- chr7:52,165,235–54,257,577, 20 genes, copy number 5: AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1.
- chr8:40,530,590–43,131,180, 60 genes, copy number 5–7 (within-gene range 1–7): ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1.
- chr8:135,859,369–137,092,183, 1 gene, copy number 5 (within-gene range 4–5): LINC02055.
- chr8:137,105,352–145,066,685, 222 genes, copy number 5 (broad region; genes not listed).
- chr9:22,703,516–23,438,700, 1 gene, copy number 6 (within-gene range 3–6): AL391117.1.
- chr9:23,291,544–23,849,914, 8 genes, copy number 6: AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1.
- chr10:15,154,802–15,171,278, 2 genes, copy number 6: PPIAP30, AL590365.1.
- chr10:15,237,492–15,241,767, 1 gene, copy number 6: AL607028.1.
- chr11:90,251,204–90,915,052, 1 gene, copy number 5 (within-gene range 3–5): DISC1FP1.
- chr11:90,731,110–92,336,496, 16 genes, copy number 5: AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1.
- chr11:92,366,496–92,498,935, 3 genes, copy number 5: PGAM1P9, AP000722.1, RPS3AP42.
- chr11:130,068,147–132,336,822, 32 genes, copy number 5 (within-gene range 3–5): APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2.
- chr13:54,572,354–59,230,636, 32 genes, copy number 5–7 (within-gene range 4–7): AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, AL159156.1.
- chr13:62,672,285–63,328,129, 3 genes, copy number 5 (within-gene range 1–5): LINC00448, AL354810.1, LINC00376.
- chr13:63,851,197–64,076,044, 2 genes, copy number 5 (within-gene range 1–5): LINC00355, NFYAP1.
- chr15:45,361,124–45,448,761, 5 genes, copy number 6 (within-gene range 3–6): GATM, SPATA5L1, C15orf48, AC025580.1, MIR147B.
- chr18:47,390–15,330,282, 376 genes, copy number 7–8 (broad region; genes not listed).
- chr20:11,234,170–16,864,148, 61 genes, copy number 8 (broad region; genes not listed).
- chr21:10,328,411–25,772,460, 209 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,289. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
